CPTAC case C3N-02586 — Bronchus and lung — Adenomas and Adenocarcinomas (CPTAC-3)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of the Clinical Proteomic Tumor Analysis Consortium (CPTAC). Disease type: Adenomas and Adenocarcinomas; Primary site: Bronchus and lung. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/8919013d-01db-4469-b0a6-553dd25fda6d

Demographics
Sex at birth: male; Race: asian; Year of birth: 1943; Vital status: Dead; Days to death: 30 days; Year of death: 2017; Cause of death: Surgical Complications; Country of birth: China.

Diagnoses (1)
1. Adenocarcinoma, NOS: ICD-O-3 morphology code: 8140/3; Tissue or organ of origin: Lung, NOS; Site of resection or biopsy: Upper lobe, lung; Age at diagnosis: 74.0 years (27,040 days); Year of diagnosis: 2017; AJCC staging edition: 7th; AJCC clinical M: M0; AJCC pathologic T: T2a; AJCC pathologic N: N1; AJCC pathologic M: MX; AJCC pathologic stage: Stage IIA; Tumor grade: G2; Residual disease: R0; Last known disease status: Tumor free; Days to last known disease status: 30 days; Progression or recurrence: no; Days to last follow up: 30 days; Tumor focality: Unifocal.
   Pathology details: Greatest tumor dimension: 3.1 cm (a second GDC size field records 2.7 cm); Lymph node involvement: Positive; Lymph nodes positive: 2; Lymph nodes tested: 23; Margin status: Uninvolved.

Follow-up (1 entry)
- Days to follow up: 30 days; Disease response: Tumor Free; Karnofsky performance status: 0; ECOG performance status: 4.

Other clinical attributes
- Weight: 74 kg; Height: 176 cm; BMI: 23.89; DLCO (% of predicted): 96; FEV1 before bronchodilator (% of reference): 74.

Exposures
- Exposure type: Tobacco; Tobacco smoking status: Current Reformed Smoker for < or = 15 yrs; Pack years smoked: 41; Cigarettes per day: 20; Tobacco smoking onset year: 1966; Tobacco smoking quit year: 2007; Alcohol history: Yes; Alcohol intensity: Not Heavy Drinker; Exposure duration years: 41.

Biospecimens (9 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample C3N-02586-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Lung; Biospecimen laterality: Right; Preservation method: Snap Frozen; Freezing method: LN2; Days to sample procurement: -11 days; Initial weight: 100 mg; Time between clamping and freezing: 27 minutes; Time between excision and freezing: 16 minutes; Method of sample procurement: Tumor Resection; Diagnosis pathologically confirmed: Yes.
  Slide C3N-02586-21: Section location: Right Upper Lobe; Percent tumor nuclei: 75; Percent necrosis: 0.
- Sample C3N-02586-02: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Lung; Biospecimen laterality: Right; Preservation method: Snap Frozen; Freezing method: LN2; Days to sample procurement: -11 days; Initial weight: 100 mg; Time between clamping and freezing: 27 minutes; Time between excision and freezing: 16 minutes; Method of sample procurement: Tumor Resection; Diagnosis pathologically confirmed: Yes.
  Slide C3N-02586-22: Section location: Right Upper Lobe; Percent tumor nuclei: 70; Percent necrosis: 0.
- Sample C3N-02586-03: Sample type: Solid Tissue Normal; Tissue type: Normal; Specimen type: Solid Tissue; Biospecimen anatomic site: Lung; Biospecimen laterality: Right; Preservation method: Snap Frozen; Freezing method: LN2; Days to sample procurement: -11 days; Initial weight: 100 mg; Time between clamping and freezing: 27 minutes; Time between excision and freezing: 16 minutes; Method of sample procurement: Surgical Resection; Diagnosis pathologically confirmed: Yes.
- Samples C3N-02586-31, C3N-02586-32, C3N-02586-72, C3N-02586-73, C3N-02586-74 (5 with the same recorded description): Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood Components NOS; Preservation method: Frozen; Freezing method: -20 (unit not recorded by GDC).
- Sample C3N-02586-71: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood Components NOS; Biospecimen anatomic site: Blood; Preservation method: Frozen; Freezing method: -20 (unit not recorded by GDC); Days to sample procurement: -11 days; Method of sample procurement: Blood Draw.
